Somatic mutation profile of tumor specimen TCGA-EM-A3AK-01A (aliquot TCGA-EM-A3AK-01A-11D-A202-08) from TCGA case TCGA-EM-A3AK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 62.7 years (22,911 days).
Specimen TCGA-EM-A3AK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7cfc0b1-3cc4-4f33-bcdc-0df2a285543b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AK-10A (Blood Derived Normal), aliquot TCGA-EM-A3AK-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aae4df64-e338-4077-b102-bf2d1a75a61b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CATSPERE | c.1493A>T p.H498L | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV63678072; called by muse, mutect2
- IL22 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1457566187, COSV60159830, COSV60160466; called by muse, mutect2
- MCC | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs866132643, COSV56729221; called by muse, mutect2, varscan2
- OR2M3 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs373560980, COSV71759064; called by muse, mutect2, varscan2
- RHPN2 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.181); catalogued as COSV54279122; called by muse, mutect2
- S100A6 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV63296851; called by muse, mutect2
- TRIM28 | c.1409+2dup p.X470_splice | Splice Site (INS) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- CFD | c.306C>A p.P102= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55048121; called by muse, mutect2
- SLC45A4 | c.321T>A p.S107= (on ENST00000517878 / NM_001286646.2; = p.S56= on NM_001080431.2) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV50139745; called by muse, mutect2, varscan2
